Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A8Q8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A8Q8-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

I-Right obturator lymph nodes:
Absence of neoplasia: (0/3)

II-Left obturator lymph node:
Absence of neoplasia: (0/1)

III-Product of amputation of the cervix:
Squamous cell carcinoma histological grade 2 infiltrating the wall in the deepest third
(measuring 1.1 cm) with no involvement of surgical margins.

Pelvic lymph nodes:
Absence of neoplasia: (0/7)

"Cyst in the left uterine tube":
Serous cyst.

Addendum:
Right and left parametrium:
Absence of neoplasia.

Absence of angiolymphatic and perineural infiltration.

ICD 10-3
Carcinoma, squamous cell NOS 8070/3
Site Cervix NOS C53.9
JW 3/8/14

Primary, Tumor Site Discrepancy		✓
HPAAs Discrepancy		✓
Primary Malignancy History		✓

Source: NCI Genomic Data Commons file 67064d05-5b85-4256-a93a-edbfd9a1f70e (TCGA-VS-A8Q8.DF0B7CA7-20B3-45CE-A25D-D4F622AF9C9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).